Gene-level copy-number profile of specimen HCM-CSHL-0082-C25-85A from HCMI case HCM-CSHL-0082-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.7 years (28,367 days).
Specimen HCM-CSHL-0082-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a527dbcc-cc89-4b26-bbc5-6d4d24c813cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0082-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/6b2cedc3-0b5f-4c0d-9a00-2e4af25c406c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 19; copy number 2: 9,797; copy number 3: 4,578; copy number 4: 42,056; copy number 5: 1,451; copy number 6: 519; copy number 7: 14; copy number 8: 178; copy number 9: 73; copy number 10: 169; copy number 11: 40; copy number 13: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 301 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:105,546,089–106,060,524, 3 genes, copy number 10 (within-gene range 8–10): ZFPM2-AS1, AC103853.1, AC103853.2.
- chr8:105,826,570–112,148,825, 56 genes, copy number 10: AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P.
- chr8:116,938,207–117,540,262, 10 genes, copy number 10: AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:118,189,455–120,373,573, 30 genes, copy number 10 (within-gene range 8–10): SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:127,578,473–127,742,951, 3 genes, copy number 10: AC104370.1, CASC11, MYC.
- chr8:133,191,039–138,083,657, 49 genes, copy number 10: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1.
- chr8:138,588,235–144,261,940, 150 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
